Somatic mutation profile of tumor specimen TCGA-24-1616-01A (aliquot TCGA-24-1616-01A-01W-0553-09) from TCGA case TCGA-24-1616, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.9 years (20,785 days).
Specimen TCGA-24-1616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3786440-3ea9-4a87-9c52-d8c0b94c74e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1616-10A (Blood Derived Normal), aliquot TCGA-24-1616-10A-01W-0553-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/261912c4-2e03-41af-9c59-49bfc2812743

The open-access MAF lists 62 somatic variants for this specimen: 52 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 46, Silent 10, Nonsense Mutation 4, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 45/51 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as rs778828612, COSV52710622; called by mutect2, varscan2
- ACADSB | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV62551507; called by muse, mutect2, varscan2
- AGXT2 | c.1493_1495del p.V498del | In Frame Del (DEL) | VAF 60/618 reads (10%) | catalogued as rs1337289502; called by mutect2, pindel
- ATP8A2 | c.2830C>T p.P944S | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54977608; called by muse, mutect2, varscan2
- ATRX | c.6518A>G p.D2173G | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100971525; called by muse, mutect2, varscan2
- CCNA1 | c.1355G>A p.C452Y | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT tolerated (1); PolyPhen benign (0.148); catalogued as COSV55224110; called by muse, mutect2, varscan2
- CDH10 | c.7A>T p.I3L | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100053278; called by muse, mutect2
- CFAP57 | c.527T>G p.M176R | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100994115; called by muse, mutect2
- DHRS4L2 | c.267T>A p.H89Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58731412; called by muse, mutect2, varscan2
- DIAPH2 | c.997A>T p.I333L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61272423; called by muse, mutect2, varscan2
- DSC3 | c.475-1G>T p.X159_splice | Splice Site (SNP) | VAF 17/92 reads (18%) | catalogued as COSV64575603; called by muse, mutect2, varscan2
- DYNC1I1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs555557277, COSV61461259; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766131360, COSV62571086; called by muse, mutect2, varscan2
- FYB1 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 191/1592 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs769282425, COSV60956564; called by muse, mutect2, varscan2
- GABRG2 | c.1451A>G p.Y484C (on ENST00000361925 / NM_001375343.1; = p.Y444C on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62722793; called by muse, mutect2, varscan2
- GCC1 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV58463856; called by muse, mutect2, varscan2
- GNPTAB | c.3223C>T p.Q1075* | Nonsense Mutation (SNP) | VAF 109/182 reads (60%) | catalogued as rs1430287278, COSV73418409; called by muse, mutect2, varscan2
- GPD2 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV60097290; called by muse, mutect2, varscan2
- GULP1 | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 71/306 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV63075309; called by muse, mutect2, varscan2
- H1-2 | c.11C>G p.T4S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs766308934, COSV59192643; called by muse, mutect2
- HAS2 | c.1471G>T p.G491C | Missense Mutation (SNP) | VAF 92/328 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58267281; called by muse, mutect2, varscan2
- IGSF3 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs777545497, COSV59598025; called by muse, mutect2, varscan2
- IKBKE | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV65627099; called by muse, mutect2, varscan2
- IVD | c.163A>G p.T55A (on ENST00000651168; = p.T52A on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV51101655; called by muse, mutect2, varscan2
- KCNH8 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60461710; called by muse, mutect2
- KCNQ5 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV59683816; called by muse, mutect2, varscan2
- KCTD7 | c.490G>A p.V164M (on ENST00000275532; = p.R177H on NM_153033.5) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.152); catalogued as rs1469857830, COSV51877741; called by muse, mutect2, varscan2
- NOTCH2NLA | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV61256232; called by mutect2, varscan2
- NXPH2 | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 24/163 reads (15%) | catalogued as COSV55646712; called by muse, mutect2, varscan2
- OR4K1 | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 268/556 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV53462752; called by muse, mutect2, varscan2
- OR5H1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 72/1436 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100641783; called by muse, mutect2
- ORC4 | c.196A>T p.I66F | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV51577297; called by muse, mutect2, varscan2
- PICALM | c.1900G>A p.V634I | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.278); catalogued as COSV62674413; called by muse, mutect2, varscan2
- PIRT | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV74119966; called by muse, mutect2, varscan2
- PLEKHG1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as COSV62050759; called by muse, mutect2, varscan2
- PPP2R1A | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV59043009, COSV59045350; called by muse, mutect2
- PTPRC | c.485C>A p.P162Q | Missense Mutation (SNP) | VAF 146/517 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV100723082, COSV61420840; called by muse, mutect2, varscan2
- SCN1A | c.3026T>C p.M1009T (on ENST00000303395 / NM_001202435.3; = p.M998T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV100322340; called by muse, mutect2, varscan2
- SCN3B | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs371558196, COSV54799755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO1B1 | c.479A>T p.K160I | Missense Mutation (SNP) | VAF 72/327 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV57017435; called by muse, mutect2
- SRGAP1 | c.1898A>G p.Y633C | Missense Mutation (SNP) | VAF 86/356 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61903854; called by muse, mutect2, varscan2
- SYN1 | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV55984980; called by muse, mutect2, varscan2
- SYT6 | c.1484C>G p.S495C (on ENST00000610222 / NM_001366225.1; = p.S410C on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV65776341; called by muse, mutect2, varscan2
- SYT6 | c.1344C>G p.I448M (on ENST00000610222 / NM_001366225.1; = p.I363M on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/531 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101059773; called by muse, mutect2
- TEDDM1 | c.710A>G p.K237R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV62380735; called by muse, mutect2, varscan2
- TRIM43 | c.89G>T p.C30F | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55529611; called by muse, mutect2, varscan2
- TTC37 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 292/415 reads (70%) | catalogued as COSV62457026; called by muse, mutect2, varscan2
- UNC79 | c.6341C>T p.S2114L (on ENST00000393151 / NM_001346218.2; = p.S1937L on NM_020818.5) | Missense Mutation (SNP) | VAF 110/373 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs968285182, COSV56403011; called by muse, mutect2, varscan2
- USH2A | c.2567A>G p.N856S | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.817); catalogued as COSV100243198; called by muse, mutect2
- VCAN | c.6727A>G p.T2243A | Missense Mutation (SNP) | VAF 57/77 reads (74%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs751656177, COSV54110114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZMYM3 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as rs754374558, COSV100078425, COSV58740856; called by muse, mutect2
- ASTN1 | c.3522G>A p.Q1174= | Silent (SNP) | VAF 88/479 reads (18%) | catalogued as COSV62507233; called by muse, mutect2, varscan2
- BCKDK | c.580C>T p.L194= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs898604240, COSV99570905; called by muse, mutect2, varscan2
- CDH8 | c.2325C>T p.Y775= | Silent (SNP) | VAF 41/176 reads (23%) | catalogued as rs765782647, CM157864, COSV54902057; called by muse, mutect2, varscan2
- GCNA | c.618C>T p.D206= | Silent (SNP) | VAF 91/371 reads (25%) | catalogued as rs778719382, COSV104424877, COSV65466386; called by muse, mutect2, varscan2
- KIDINS220 | c.1812A>G p.R604= | Silent (SNP) | VAF 272/1311 reads (21%) | catalogued as COSV56759424; called by muse, mutect2, varscan2
- PLPPR4 | c.1983C>T p.Y661= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs1375592492, COSV64567796; called by muse, mutect2, varscan2
- SPATA31D1 | c.4218G>A p.R1406= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV61201616; called by muse, mutect2, varscan2
- STAB2 | c.5622C>T p.A1874= | Silent (SNP) | VAF 55/196 reads (28%) | catalogued as COSV66347534; called by muse, mutect2, varscan2
- TNKS2 | c.1407T>C p.A469= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as rs369522806; called by muse, mutect2
- TNPO3 | c.2391G>A p.R797= | Silent (SNP) | VAF 36/226 reads (16%) | catalogued as COSV55287204; called by muse, mutect2, varscan2
